Gene-level copy-number profile of tumor specimen ALCH-ACGT-TTP1-A from ALCHEMIST case ALCH-ACGT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.0 years (21,919 days).
Specimen ALCH-ACGT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b97ac070-8574-46b3-9169-4b5111fda485.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ACGT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/0b870562-0a9c-49f8-965b-4605455e7a81

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 142; copy number 1: 1,607; copy number 2: 24,319; copy number 3: 8,716; copy number 4: 16,555; copy number 5: 4,934; copy number 6: 818; copy number 7: 525; copy number 8: 537; copy number 9: 10; copy number 10: 26; copy number 11: 27; copy number 13: 33; copy number 14: 5; copy number 15: 37; copy number 18: 92.

Homozygous deletions (total copy number 0; autosomes only): 142 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:6,892,632–6,894,022, 1 gene (within-gene range 0–1): GRM7-AS2.
- chr4:268,982–305,474, 3 genes: AC079140.3, AC079140.5, ZNF732.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr7:10,901,978–12,700,889, 23 genes: Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1.
- chr7:12,876,684–12,922,920, 2 genes: RN7SKP228, RBMX2P4.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:20,331,446–23,672,399, 73 genes (broad region; genes not listed).
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr10:87,341,685–87,357,882, 1 gene (within-gene range 0–2): LINC00863.
- chr19:23,304,991–24,163,425, 29 genes: ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,164 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–157,138,474, 632 genes, copy number 5–8 (broad region; genes not listed).
- chr1:184,690,237–196,747,504, 115 genes, copy number 5 (broad region; genes not listed).
- chr1:234,391,313–236,221,865, 57 genes, copy number 5 (within-gene range 4–5): TARBP1, LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1, B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, GPR137B.
- chr2:42,143,238–62,533,059, 315 genes, copy number 5 (broad region; genes not listed).
- chr2:76,747,719–86,912,978, 137 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:89,319,625–89,600,680, 3 genes, copy number 14: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:111,119,378–113,658,675, 83 genes, copy number 5 (broad region; genes not listed).
- chr6:105,919–170,631, 3 genes, copy number 9: OR4F1P, CICP18, AL035696.2.
- chr7:1,614,590–4,794,397, 45 genes, copy number 6–8: TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1, AC017000.1, CYP3A54P, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1.
- chr7:13,854,355–38,025,695, 402 genes, copy number 5–13 (broad region; genes not listed).
- chr7:49,760,897–50,793,462, 17 genes, copy number 5: AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1.
- chr7:53,187,388–56,080,670, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:62,275,361–63,621,169, 39 genes, copy number 5–7: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2.
- chr7:146,050,062–152,855,378, 157 genes, copy number 5 (broad region; genes not listed).
- chr8:42,836,674–43,674,591, 33 genes, copy number 5–6: THAP1, AC087533.1, RN7SL806P, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:64,570,913–64,583,627, 3 genes, copy number 6: AC090136.2, AC090136.3, BHLHE22.
- chr8:122,977,026–145,066,685, 418 genes, copy number 6 (broad region; genes not listed).
- chr10:21,492,658–21,526,368, 3 genes, copy number 6: MIR1915HG, MIR1915, SKIDA1.
- chr11:86,649–13,758,345, 558 genes, copy number 7–8 (broad region; genes not listed).
- chr11:45,885,651–46,121,454, 6 genes, copy number 6–7 (within-gene range 2–7): MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A.
- chr11:54,591,480–55,389,472, 22 genes, copy number 6: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P.
- chr11:85,628,573–85,811,159, 5 genes, copy number 5: TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2.
- chr12:564,296–911,452, 9 genes, copy number 5: NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1.
- chr13:78,761,175–80,341,126, 17 genes, copy number 6: RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, LINC01038, LINC00382, AL158064.1, LINC01080, SPRY2.
- chr13:111,095,838–111,305,737, 8 genes, copy number 7: LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1.
- chr13:112,647,044–114,337,626, 54 genes, copy number 5: ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:21,868,839–23,183,674, 157 genes, copy number 5 (broad region; genes not listed).
- chr14:28,318,141–30,373,115, 29 genes, copy number 14–15: AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1.
- chr14:32,879,246–38,606,098, 102 genes, copy number 15–18 (broad region; genes not listed).
- chr14:91,232,532–91,259,003, 3 genes, copy number 6: GPR68, AL135818.1, AL135818.2.
- chr14:97,427,071–104,978,374, 304 genes, copy number 5–7 (broad region; genes not listed).
- chr15:84,186,752–84,245,368, 4 genes, copy number 5: CSPG4P11, GOLGA2P7, RN7SL331P, GOLGA6L4.
- chr17:21,592,794–32,881,070, 336 genes, copy number 5 (broad region; genes not listed).
- chr17:35,192,520–50,631,940, 800 genes, copy number 5–8 (broad region; genes not listed).
- chr17:56,834,107–68,551,319, 376 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:80,801,640–83,240,804, 149 genes, copy number 5 (broad region; genes not listed).
- chr18:45,034–21,870,953, 390 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:48,600,810–48,624,132, 4 genes, copy number 7 (within-gene range 2–7): FAM83E, SPACA4, RPL18, AC022154.1.
- chr20:30,214,765–32,207,743, 62 genes, copy number 5 (broad region; genes not listed).
- chr22:15,282,557–20,390,758, 231 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,410. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
